Somatic mutation profile of tumor specimen TCGA-UF-A7JA-01A (aliquot TCGA-UF-A7JA-01A-12D-A34J-08) from TCGA case TCGA-UF-A7JA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.0 years (24,121 days).
Specimen TCGA-UF-A7JA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1efc6f36-871d-4491-a65d-927732dd8ba4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7JA-10A (Blood Derived Normal), aliquot TCGA-UF-A7JA-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a5c8054-7693-4064-9fc4-362e0d38cf3c

The open-access MAF lists 210 somatic variants for this specimen: 162 protein-altering or splice-affecting, 44 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 44, Nonsense Mutation 9, RNA 3, Frame Shift Ins 1, Splice Region 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 21/113 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 34/253 reads (13%) | catalogued as rs869312782, COSV52692559, COSV52721885, COSV53153630, COSV53758203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD4 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.919); catalogued as COSV100084034; called by muse, mutect2
- ABCD4 | c.123G>C p.L41F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV100084037; called by muse, mutect2
- ADAM22 | c.554A>C p.H185P | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99715848; called by muse, mutect2, varscan2
- ADAMTS12 | c.3555T>A p.N1185K | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100710334; called by muse, mutect2, varscan2
- ADGRF2 | c.895G>T p.G299* (on ENST00000296862 / NM_001368115.2; = p.G231* on NM_153839.7) | Nonsense Mutation (SNP) | VAF 17/136 reads (13%) | catalogued as COSV99730774; called by muse, mutect2, varscan2
- AKAP8L | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs541815464, COSV101275727; called by muse, mutect2
- AKAP9 | c.3946G>A p.D1316N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV100661951; called by muse, mutect2, varscan2
- AL121899.2 | c.1767C>G p.I589M | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV101198388; called by muse, mutect2, varscan2
- ANKRD50 | c.2239G>C p.D747H | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101538888; called by muse, mutect2, varscan2
- AOX1 | c.3560T>A p.I1187N | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99613396; called by muse, mutect2, varscan2
- APC | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57327935, COSV99965567; called by muse, mutect2, varscan2
- ARFGEF2 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100904013; called by muse, mutect2
- BPTF | c.5501A>G p.Y1834C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); catalogued as rs1479452929, COSV100074179; called by muse, mutect2, varscan2
- BRCA2 | c.935T>G p.F312C | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV101203964; called by muse, mutect2, varscan2
- C5orf46 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as COSV100568368; called by muse, mutect2, varscan2
- CABIN1 | c.5899C>T p.R1967C | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as COSV54085149; called by muse, mutect2, varscan2
- CAMSAP1 | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.771); catalogued as COSV100409610; called by muse, mutect2
- CAPN1 | c.1380G>C p.L460F | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99658385; called by muse, mutect2
- CCDC198 | c.25C>T p.H9Y | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs759752791, COSV99371141; called by muse, mutect2
- CDH10 | c.218A>T p.Q73L | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.077); catalogued as COSV100050209, COSV52579902; called by muse, mutect2, varscan2
- CDH23 | c.8813C>A p.A2938E | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs770584130, COSV99819083; called by muse, mutect2, varscan2
- CDH26 | c.601C>G p.Q201E | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV99721852; called by muse, mutect2
- CEP57 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100334588; called by muse, mutect2, varscan2
- CFHR3 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100807424; called by muse, mutect2
- CLPX | c.659C>G p.S220* | Nonsense Mutation (SNP) | VAF 22/223 reads (10%) | catalogued as COSV100269313; called by muse, mutect2, varscan2
- CNTN6 | c.2300G>C p.S767T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.061); catalogued as rs1447358402, COSV100610120; called by muse, mutect2, varscan2
- COL19A1 | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100505286; called by muse, mutect2, varscan2
- COL4A3 | c.894A>T p.K298N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV101169974; called by muse, mutect2, varscan2
- COPRS | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 33/379 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100188337; called by muse, mutect2
- CREBBP | c.4243C>T p.Q1415* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as COSV52122115; called by muse, mutect2
- CRMP1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV100271410; called by muse, mutect2, varscan2
- CSMD3 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1564168791, COSV52105622, COSV52155991; called by muse, mutect2
- CSMD3 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 47/463 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); catalogued as COSV52158616, COSV99825905, COSV99850486; called by muse, mutect2, varscan2
- DDHD1 | c.1332T>A p.S444R (on ENST00000323669; = p.S641R on NM_030637.3) | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV100079100; called by muse, mutect2, varscan2
- DGKB | c.2325G>C p.K775N | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99336743; called by muse, varscan2
- DHX32 | c.200A>G p.E67G | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV99501392; called by muse, mutect2
- DMXL2 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99195990; called by muse, mutect2, varscan2
- DNAH5 | c.11176C>T p.Q3726* | Nonsense Mutation (SNP) | VAF 10/129 reads (8%) | catalogued as rs867684159, COSV54208224; called by muse, mutect2
- DPP10 | c.1730C>A p.T577K | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV100059362, COSV59684777; called by muse, mutect2
- DPY19L2 | c.1375C>G p.L459V | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs201623035, COSV100116545; called by muse, mutect2
- DSCAM | c.3605C>G p.A1202G | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV101259204; called by muse, mutect2, varscan2
- DSEL | c.2042T>G p.M681R | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV100025315; called by muse, mutect2, varscan2
- DSEL | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374886894; called by muse, mutect2, varscan2
- EFCAB13 | c.929C>G p.S310* | Nonsense Mutation (SNP) | VAF 14/151 reads (9%) | catalogued as rs1289744407, COSV100516354; called by muse, mutect2
- ELAPOR2 | c.2454T>C p.Y818= (on ENST00000450689 / NM_001142749.3; = p.Y651= on NM_152748.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 19/126 reads (15%) | catalogued as rs771145375, COSV99788243; called by muse, mutect2, varscan2
- EMC2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); catalogued as COSV99623900; called by muse, mutect2
- FAM83D | c.1327C>G p.Q443E | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV54156355, COSV54158010, COSV99465009; called by muse, mutect2
- FBXO15 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99503075; called by muse, mutect2, varscan2
- FCER1A | c.53T>C p.F18S | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV63667415; called by muse, mutect2
- FMNL2 | c.1387C>G p.Q463E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV99978989; called by muse, mutect2, varscan2
- FN1 | c.1120T>A p.C374S | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100116228; called by muse, mutect2
- FREM2 | c.6728G>C p.R2243P | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV99747010, COSV99751445; called by muse, mutect2, varscan2
- GAD2 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99392625; called by muse, mutect2
- GCC2 | c.3430G>C p.E1144Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV100565267, COSV59176843; called by muse, mutect2, varscan2
- GOLGA4 | c.3223G>A p.E1075K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV62713491; called by muse, mutect2, varscan2
- GPR37 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.015); catalogued as COSV100390562; called by muse, mutect2, varscan2
- GPR65 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs769412319, COSV50864032; called by muse, mutect2, varscan2
- GRIK2 | c.2542_2543insT p.K848Ifs*12 | Frame Shift Ins (INS) | VAF 18/191 reads (9%) | catalogued as COSV100023433; called by mutect2, pindel
- GRINA | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as rs1554750383, COSV100477741; called by muse, mutect2, varscan2
- GRM3 | c.2029G>T p.A677S | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs563221454, COSV100862145, COSV64470856; called by muse, mutect2
- GRM3 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV100862146; called by muse, mutect2
- GUCA1C | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.107); catalogued as COSV99659525; called by muse, mutect2
- HAUS2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752563550, COSV99535297; called by muse, mutect2, varscan2
- HSP90AA1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.337); catalogued as COSV53491637, COSV99355034; called by muse, mutect2, varscan2
- IGF2BP1 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as COSV99288290; called by muse, mutect2, varscan2
- INSYN2A | c.914T>A p.L305Q | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV99726955; called by muse, mutect2
- JAKMIP1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.996); catalogued as COSV51525099; called by muse, mutect2
- KCNAB1 | c.418G>A p.E140K (on ENST00000490337 / NM_172160.3; = p.E129K on NM_003471.3) | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919946760, COSV56740913; called by muse, mutect2
- KCNH1 | c.2914G>C p.E972Q (on ENST00000271751 / NM_172362.3; = p.E945Q on NM_002238.4) | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV99657511; called by muse, mutect2
- KCNK16 | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV100949088, COSV64678513; called by muse, mutect2, varscan2
- KMT2E | c.1513C>A p.Q505K | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV99995845; called by muse, mutect2
- KNDC1 | c.3462G>T p.Q1154H | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as COSV100463478, COSV58843609; called by muse, mutect2
- KRIT1 | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100388608; called by muse, mutect2, varscan2
- LRRC31 | c.1118T>G p.I373S | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV99246342; called by muse, mutect2
- LRRCC1 | c.1221G>C p.K407N | Missense Mutation (SNP) | VAF 20/327 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.192); catalogued as COSV100835298; called by muse, mutect2
- LRRK2 | c.6518A>C p.H2173P | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100109353; called by muse, mutect2
- MACF1 | c.15793G>A p.E5265K (on ENST00000372915; = p.E3198K on NM_012090.5) | Missense Mutation (SNP) | VAF 14/190 reads (7%) | catalogued as rs1274396968, COSV57131495; called by muse, mutect2
- MAGEB1 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100974852, COSV66776028; called by muse, mutect2
- MAGEC1 | c.3179C>A p.P1060H | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99594936; called by muse, mutect2, varscan2
- MAST3 | c.2980G>C p.E994Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99444508; called by muse, mutect2, varscan2
- MCM7 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770263756, COSV100384687; called by muse, mutect2
- MEPE | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.22); catalogued as COSV100734857; called by muse, mutect2, varscan2
- METTL8 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1381658180, COSV100930959; called by muse, mutect2
- MGA | c.3179G>A p.S1060N | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99578684; called by muse, mutect2, varscan2
- MLH1 | c.1939G>C p.V647L | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99212335; called by muse, mutect2, varscan2
- MYH4 | c.1032C>A p.F344L | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99700395, COSV99700414; called by muse, mutect2, varscan2
- NDC80 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99859460; called by muse, mutect2, varscan2
- NEDD9 | c.1321A>G p.M441V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1408734677, COSV101060772; called by muse, mutect2, varscan2
- NHS | c.4232T>G p.F1411C | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101196421; called by muse, varscan2
- NLRP14 | c.1396A>T p.I466F | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV100204616; called by muse, mutect2, varscan2
- NT5E | c.1403G>C p.R468T | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100003897; called by muse, mutect2
- OR1A1 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV58404960; called by muse, mutect2, varscan2
- OR51F2 | c.918C>G p.I306M | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100437921, COSV59065179; called by muse, mutect2, varscan2
- OR5H14 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101454077; called by muse, mutect2, varscan2
- OR5M11 | c.853A>G p.N285D | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV101602020; called by muse, varscan2
- OR6M1 | c.317G>C p.G106A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100484020; called by muse, mutect2, varscan2
- OR7A17 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV100541570; called by muse, mutect2
- PCDH11X | c.2905G>C p.D969H | Missense Mutation (SNP) | VAF 23/310 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100008646; called by muse, mutect2
- PCDHA11 | c.750C>A p.S250R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as rs1408875478, COSV100247908; called by muse, mutect2
- PCDHA3 | c.1886G>C p.G629A | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100793178; called by muse, mutect2
- PCDHGA6 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as rs748938190, COSV99531635; called by muse, mutect2, varscan2
- PDZRN4 | c.1609G>T p.G537C (on ENST00000402685 / NM_001164595.2; = p.G279C on NM_013377.4) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100113702; called by muse, varscan2
- PHAX | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99881295; called by muse, mutect2
- PHLPP2 | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.073); catalogued as COSV100673517; called by muse, mutect2, varscan2
- PIK3R4 | c.3140C>T p.T1047M | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs749751291, COSV100768255; called by muse, mutect2, varscan2
- PLCH1 | c.4754G>C p.R1585T (on ENST00000340059 / NM_001130960.2; = p.R1577T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100395703; called by muse, mutect2
- PNPLA4 | c.239C>A p.A80E | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101124362; called by muse, mutect2
- PPP1R3A | c.3146C>T p.S1049F | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.331); catalogued as COSV52890976; called by muse, mutect2
- PRDM9 | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs1450853481, COSV57004243; called by muse, varscan2
- PROS1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 20/212 reads (9%) | catalogued as COSV100820203; called by muse, mutect2
- PRPF4B | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV100528034; called by muse, mutect2, varscan2
- PRSS35 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1460269196, COSV63800358, COSV63801021; called by muse, mutect2, varscan2
- PZP | c.3428A>G p.E1143G | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV99736400; called by muse, mutect2, varscan2
- QRFPR | c.888T>G p.I296M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100543481; called by muse, mutect2, varscan2
- RAD50 | c.2174G>T p.R725L | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs372808845, COSV99528628; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGS3 | c.3294G>C p.E1098D (on ENST00000350696 / NM_001282923.2; = p.E817D on NM_130795.4) | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100636566; called by muse, mutect2
- RNF6 | c.107G>C p.R36T | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100644582; called by muse, mutect2, varscan2
- RNMT | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs868206894, COSV100054470; called by muse, mutect2
- SCLT1 | c.1367C>G p.S456* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99827641; called by muse, mutect2, varscan2
- SERINC5 | c.1238A>G p.K413R | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV101549052; called by muse, mutect2
- SESTD1 | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV101468046; called by muse, mutect2
- SLAMF1 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99348970; called by muse, mutect2, varscan2
- SLC7A6 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.329); catalogued as COSV99546425; called by muse, mutect2
- SLFN13 | c.2264A>T p.N755I | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV53192172, COSV99539757; called by muse, mutect2, varscan2
- SLITRK3 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs755352126, COSV53853476; called by muse, mutect2
- SMARCC2 | c.1315C>G p.H439D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99910866; called by muse, mutect2
- SORCS3 | c.2625C>G p.I875M | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as COSV100863404, COSV63793264, COSV63794690; called by muse, mutect2
- TAF5 | c.1656T>A p.S552R | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100674592; called by muse, mutect2, varscan2
- TLE4 | c.1678T>C p.W560R | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99511296; called by muse, mutect2, varscan2
- TNFAIP3 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs780709741, COSV52797532; called by muse, mutect2, varscan2
- TNIP3 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.663); catalogued as COSV50246777, COSV50246992, COSV99284293; called by muse, mutect2
- TPR | c.5233A>G p.S1745G | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV100823667; called by muse, mutect2, varscan2
- TRANK1 | c.3338A>T p.E1113V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV100081684; called by muse, mutect2
- TRIM45 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99868245; called by muse, mutect2, varscan2
- TRIM45 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as COSV99868247, COSV99868735; called by muse, mutect2, varscan2
- TRIM48 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV101338199; called by muse, mutect2
- TRPA1 | c.3338A>C p.K1113T | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV100083287; called by muse, mutect2, varscan2
- TSPYL5 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.052); catalogued as COSV59072205, COSV59073095; called by muse, mutect2, varscan2
- UPF1 | c.1283C>T p.S428L (on ENST00000599848 / NM_001297549.2; = p.S417L on NM_002911.4) | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV99438868; called by muse, mutect2
- USP31 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54852261, COSV99564684; called by muse, mutect2, varscan2
- VPS13B | c.6109C>G p.L2037V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100660924; called by muse, mutect2, varscan2
- VPS13D | c.3525A>T p.L1175F | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV99165545; called by muse, mutect2, varscan2
- VPS50 | c.2156C>G p.S719C | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.237); catalogued as rs549768202, COSV100004525; called by muse, mutect2
- WDR46 | c.814A>T p.I272F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV101004719; called by muse, mutect2, varscan2
- XAGE5 | c.194C>A p.A65D | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV100657792; called by muse, mutect2, varscan2
- XRN2 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.885); catalogued as rs771948880, COSV101018032, COSV65870602; called by muse, mutect2, varscan2
- ZFHX3 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.392); catalogued as rs769010742, COSV51707324; called by muse, mutect2, varscan2
- ZNF226 | c.611A>G p.D204G | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100335025; called by muse, mutect2
- ZNF254 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as rs1329756323, COSV100741516; called by muse, mutect2, varscan2
- ZNF462 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99470870; called by muse, mutect2
- ZNF567 | c.1572G>C p.Q524H (on ENST00000536254 / NM_001322913.1; = p.Q493H on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV100658644; called by muse, mutect2, varscan2
- ZNF649 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100030806; called by muse, mutect2, varscan2
- ZNF813 | c.700C>G p.Q234E | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV101124673, COSV101124695; called by muse, mutect2
- ZSCAN4 | c.724A>G p.N242D | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.118); catalogued as COSV99989759; called by muse, mutect2, varscan2
- IGHG4 | c.788G>C p.S263T | Missense Mutation (SNP) | VAF 61/511 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- LAMA2 | c.6909G>A p.M2303I | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- LAMB1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- MZF1 | c.652-1G>A p.X218_splice | Splice Site (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- TRANK1 | c.3337G>T p.E1113* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- ZNF622 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 32/479 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD30A | c.3663T>C p.P1221= (on ENST00000611781; = p.P1165= on NM_052997.2) | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV100652990; called by muse, mutect2, varscan2
- AXL | c.1995C>G p.T665= (on ENST00000301178 / NM_021913.5; = p.T656= on NM_001699.6) | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV99995693, COSV99995972; called by muse, mutect2
- CACNA2D1 | c.3066G>C p.G1022= (on ENST00000356253 / NM_001366867.1; = p.G1010= on NM_000722.4) | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV100666032; called by muse, mutect2, varscan2
- CFAP46 | c.609G>A p.P203= | Silent (SNP) | VAF 33/282 reads (12%) | catalogued as rs754603805, COSV100886291; called by muse, mutect2, varscan2
- CHRNA9 | c.621C>T p.G207= | Silent (SNP) | VAF 33/308 reads (11%) | catalogued as COSV59574444; called by muse, mutect2, varscan2
- CLTRN | c.81G>T p.V27= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100982187; called by muse, mutect2
- DMXL2 | c.1686C>T p.I562= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV99195991; called by muse, mutect2, varscan2
- DOCK6 | c.1407C>T p.D469= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs1275113872, COSV52949756; called by muse, mutect2, varscan2
- DTYMK | c.519G>A p.L173= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as COSV99994680; called by muse, mutect2, varscan2
- ERCC1 | c.546C>G p.L182= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV50004754; called by muse, mutect2, varscan2
- GABRA5 | c.1209C>G p.V403= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100164788, COSV100165355; called by muse, mutect2
- GCN1 | c.2418C>T p.I806= | Silent (SNP) | VAF 25/187 reads (13%) | catalogued as rs372829636; called by muse, mutect2, varscan2
- HDAC6 | c.3507A>T p.G1169= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100490595; called by muse, mutect2
- IFNA21 | c.273C>T p.F91= | Silent (SNP) | VAF 24/225 reads (11%) | catalogued as COSV101207411; called by muse, mutect2, varscan2
- IGSF5 | c.654C>A p.T218= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV101011977; called by muse, mutect2, varscan2
- IMPG1 | c.1185G>T p.L395= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV64058696; called by muse, mutect2, varscan2
- KCNIP2 | c.513G>C p.V171= (on ENST00000356640 / NM_173191.3; = p.V186= on NM_014591.5) | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV99493165; called by muse, mutect2, varscan2
- KCNJ5 | c.687C>T p.I229= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs149327599; called by muse, mutect2, varscan2
- KCNMB3 | c.60G>A p.T20= | Silent (SNP) | VAF 17/224 reads (8%) | catalogued as rs760056658, COSV100046461; called by muse, mutect2
- KLHL38 | c.1506C>G p.V502= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV100384271; called by muse, mutect2
- KSR2 | c.1923G>A p.S641= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs377379360; called by muse, mutect2, varscan2
- LILRA2 | c.390C>T p.S130= | Silent (SNP) | VAF 33/426 reads (8%) | called by muse, mutect2
- LRP2 | c.6153C>G p.L2051= | Silent (SNP) | VAF 15/193 reads (8%) | catalogued as COSV99786718; called by muse, mutect2
- LRRIQ4 | c.384C>T p.T128= | Silent (SNP) | VAF 14/145 reads (10%) | catalogued as rs1217636845, COSV61618871; called by muse, mutect2, varscan2
- MAG | c.1455C>T p.R485= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV62701448; called by muse, mutect2, varscan2
- MAP3K5 | c.3081T>C p.D1027= | Silent (SNP) | VAF 30/312 reads (10%) | catalogued as COSV100752531; called by muse, mutect2
- NUSAP1 | c.234G>A p.E78= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99530745; called by muse, mutect2, varscan2
- OR4C15 | c.381A>T p.S127= (on ENST00000314644; = p.S73= on NM_001001920.2) | Silent (SNP) | VAF 47/264 reads (18%) | catalogued as COSV100115413; called by muse, mutect2, varscan2
- OR5H14 | c.720C>A p.T240= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV101454078; called by muse, mutect2, varscan2
- OR6C1 | c.474C>G p.L158= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV65572842; called by muse, mutect2, varscan2
- OR8H2 | c.756T>C p.Y252= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as rs1412506500, COSV100542159; called by muse, mutect2
- PRKAG1 | c.228T>C p.D76= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs371515098; called by muse, mutect2, varscan2
- RAB4B | c.546G>A p.R182= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs1024697772, COSV100826419; called by muse, mutect2, varscan2
- SEMA4D | c.1965C>A p.A655= | Silent (SNP) | VAF 68/316 reads (22%) | catalogued as COSV100357978; called by muse, mutect2, varscan2
- SPAG6 | c.168A>T p.T56= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV100509963; called by muse, mutect2, varscan2
- SYCP2 | c.1953T>C p.T651= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100697996; called by muse, mutect2, varscan2
- TBC1D25 | c.576C>G p.V192= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100952112; called by muse, mutect2, varscan2
- TERT | c.2733C>T p.D911= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as rs768646695, COSV57204613; ClinVar: likely benign; called by muse, mutect2
- TTC39C | c.501G>A p.K167= (on ENST00000317571 / NM_001135993.2; = p.K106= on NM_153211.4) | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as COSV100455177; called by muse, varscan2
- TTN | c.20586A>G p.K6862= (on ENST00000591111; = p.K5935= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100596199, COSV59982431; called by muse, mutect2, varscan2
- UVSSA | c.1401C>G p.L467= | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as COSV101104321; called by muse, mutect2
- ZHX1 | c.435A>G p.E145= | Silent (SNP) | VAF 37/222 reads (17%) | catalogued as COSV99933499; called by muse, mutect2, varscan2
- ZNF468 | c.663C>T p.F221= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV99700361; called by muse, mutect2, varscan2
- ZNF519 | c.1494C>T p.T498= | Silent (SNP) | VAF 11/142 reads (8%) | catalogued as COSV101645550; called by muse, mutect2
- PMS2P3 | n.421G>T | RNA (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- SNORD115-48 | n.25G>A | RNA (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- TMEM183B | n.943C>A | RNA (SNP) | VAF 38/540 reads (7%) | called by muse, mutect2
- TTLL8 | c.938+399A>G | Intron (SNP) | VAF 43/180 reads (24%) | catalogued as COSV99838039; called by muse, mutect2, varscan2
